Somatic mutation profile of tumor specimen TCGA-DU-7304-02A (aliquot TCGA-DU-7304-02A-12D-A36O-08) from TCGA case TCGA-DU-7304, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 43.6 years (15,931 days).
Specimen TCGA-DU-7304-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b85d6533-7724-4db5-a6ba-21f7f94b24b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7304-10A (Blood Derived Normal), aliquot TCGA-DU-7304-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26d3ba76-6138-4aa8-a340-cdfcb89f7c38

The open-access MAF lists 81 somatic variants for this specimen: 63 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Splice Site 3, Intron 1, In Frame Del 1, Nonsense Mutation 1, 3'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 41/99 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP3K1 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1287268127, COSV68121509, COSV68122713; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1del p.X125_splice | Splice Site (DEL) | VAF 23/80 reads (29%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by mutect2, pindel, varscan2
- AKR7L | c.784A>C p.M262L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761743656, COSV70167506; called by muse, mutect2, varscan2
- ARGFX | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 149/288 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100544070; called by muse, mutect2, varscan2
- ARHGEF12 | c.3017A>G p.N1006S | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100754695; called by muse, mutect2
- ATG5 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.326); catalogued as COSV58347780; called by muse, mutect2, varscan2
- ATP10D | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1462262033, COSV99905258; called by muse, mutect2
- BTNL3 | c.1057T>A p.W353R | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100732181; called by muse, mutect2, varscan2
- CDH19 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100050975; called by muse, mutect2, varscan2
- CHRNA1 | c.767C>T p.P256L (on ENST00000261007 / NM_001039523.3; = p.P231L on NM_000079.4) | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs985035699, COSV99650194; called by muse, mutect2
- COL14A1 | c.5381C>A p.P1794H | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV99918212; called by muse, mutect2
- COL6A1 | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100719977; called by muse, mutect2
- CYP26B1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV99134285; called by muse, mutect2
- DCAF17 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 156/326 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100266008; called by muse, mutect2, varscan2
- DIPK2A | c.1189G>C p.A397P | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); catalogued as COSV59857245; called by muse, mutect2, varscan2
- FAM124A | c.202G>A p.V68I (on ENST00000322475 / NM_001242312.2; = p.V104I on NM_145019.4) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); catalogued as rs1433534038, COSV54475053; called by muse, mutect2, varscan2
- FN1 | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1164875781, COSV100116295; called by muse, mutect2, varscan2
- FOSB | c.652C>G p.H218D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100798701; called by mutect2, varscan2
- GAS2L2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1266412002; called by muse, mutect2
- GPAA1 | c.515-1G>C p.X172_splice | Splice Site (SNP) | VAF 6/99 reads (6%) | catalogued as COSV100283977; called by muse, mutect2
- GPR119 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767108536, COSV52276857; called by muse, mutect2
- H2AC1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV51237789; called by muse, mutect2, varscan2
- HAS3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1413838677, COSV54706978; called by muse, mutect2, varscan2
- HSPG2 | c.12476G>T p.C4159F | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100760709; called by muse, mutect2, varscan2
- IDO2 | c.556G>C p.V186L (on ENST00000389060; = p.V199L on NM_194294.2) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV100584567; called by muse, mutect2, varscan2
- ITIH1 | c.1420C>G p.Q474E | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99834979; called by muse, mutect2, varscan2
- KIF6 | c.1828A>G p.I610V | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV54676466; called by muse, mutect2, varscan2
- MCM10 | c.1568T>C p.M523T (on ENST00000484800 / NM_182751.3; = p.M522T on NM_018518.5) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs937968185, COSV101097966; called by muse, mutect2, varscan2
- MDC1 | c.4717C>G p.P1573A | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV100902637; called by muse, mutect2
- MECOM | c.50A>G p.E17G (on ENST00000468789 / NM_001105078.4; = p.E205G on NM_004991.4) | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV99244186; called by muse, mutect2
- MS4A4A | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs763636845, COSV100557719; called by muse, mutect2, varscan2
- NELL1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.558); catalogued as rs908099186, COSV54262173; called by mutect2, varscan2
- OIT3 | c.791-1G>C p.X264_splice | Splice Site (SNP) | VAF 107/257 reads (42%) | catalogued as COSV61825919; called by muse, mutect2, varscan2
- OR4C46 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100060443, COSV100060659; called by muse, mutect2, varscan2
- OR5L1 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100449934, COSV61735384; called by muse, mutect2
- PENK | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs148671012; called by muse, mutect2, varscan2
- PNPLA6 | c.1249C>T p.R417C (on ENST00000414982 / NM_001166111.2; = p.R369C on NM_006702.5) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs998008899, COSV55377935; called by muse, mutect2, varscan2
- PRDM15 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.557); catalogued as rs753342130, COSV99519432; called by muse, mutect2, varscan2
- PRR27 | c.31T>C p.C11R | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100748758; called by muse, mutect2, varscan2
- PTCHD4 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs191919500, COSV100260253; called by muse, mutect2, varscan2
- PTPN11 | c.1424T>G p.L475R | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100692210, COSV61004950; called by muse, mutect2
- RP1L1 | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV101222993; called by muse, mutect2
- RYR1 | c.3299G>A p.R1100H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755973279, COSV62110112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAGE1 | c.2340T>G p.D780E | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as COSV100186763; called by muse, mutect2, varscan2
- SARS2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs369247597; called by muse, mutect2, varscan2
- SLC25A19 | c.721A>T p.K241* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV100237444; called by muse, mutect2
- SLCO5A1 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV99479491; called by muse, mutect2, varscan2
- SLITRK6 | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.444); catalogued as COSV101233183; called by muse, mutect2
- SNTG1 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99381713; called by muse, mutect2, varscan2
- SORCS2 | c.1527C>A p.D509E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as rs764912606, COSV100211677; called by muse, varscan2
- SPRED2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV62694546; called by muse, mutect2
- SPTBN5 | c.3517T>C p.C1173R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV58020363; called by muse, mutect2, varscan2
- SYT10 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs755675734, COSV57339421; called by muse, mutect2, varscan2
- TCERG1L | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100893922; called by muse, mutect2, varscan2
- TPPP2 | c.17A>C p.E6A | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV53875041; called by muse, mutect2, varscan2
- TRMT9B | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs537507417, COSV101501523; called by muse, mutect2, varscan2
- UTRN | c.10148A>C p.D3383A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.165); catalogued as COSV100838204; called by muse, mutect2, varscan2
- ATRX | c.4919del p.K1640Sfs*6 | Frame Shift Del (DEL) | VAF 47/69 reads (68%) | called by mutect2, pindel, varscan2
- CHM | c.1045dup p.S349Kfs*69 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CYFIP1 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- NR4A1 | c.1391_1393del p.F464del | In Frame Del (DEL) | VAF 22/50 reads (44%) | called by pindel, varscan2
- CNTN1 | c.1860G>A p.V620= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs1397245454, COSV100751016; called by muse, mutect2, varscan2
- CREB3L3 | c.594G>T p.G198= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as COSV99313899; called by muse, mutect2
- DAPL1 | c.114A>G p.R38= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV59354326; called by muse, mutect2
- DYRK4 | c.1560A>G p.V520= | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as rs751076723, COSV99155488; called by muse, mutect2, varscan2
- GLOD4 | c.900C>T p.D300= (on ENST00000301328 / NM_001366247.1; = p.D285= on NM_016080.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs116004401; called by muse, mutect2, varscan2
- IL10 | c.190T>C p.L64= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100894728; called by muse, mutect2, varscan2
- MECP2 | c.261C>T p.I87= | Silent (SNP) | VAF 118/122 reads (97%) | catalogued as COSV57653684; called by muse, mutect2, varscan2
- MTHFD2L | c.439T>C p.L147= (on ENST00000395759 / NM_001144978.2; = p.L89= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/136 reads (4%) | catalogued as COSV100305857; called by muse, mutect2
- OR6A2 | c.444G>A p.Q148= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100215612, COSV60264323; called by muse, mutect2
- PKHD1 | c.7206T>A p.G2402= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100581449; called by muse, mutect2, varscan2
- PLXDC1 | c.558C>T p.Y186= | Silent (SNP) | VAF 81/169 reads (48%) | catalogued as COSV100195036; called by muse, mutect2, varscan2
- PSG4 | c.639A>G p.G213= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as rs756206359, COSV99736405; called by muse, mutect2
- RIN3 | c.276C>T p.S92= | Silent (SNP) | VAF 144/267 reads (54%) | catalogued as rs1458073505, COSV99378604; called by muse, mutect2, varscan2
- SLCO1A2 | c.1989T>C p.D663= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV56601659; called by muse, mutect2, varscan2
- TPCN2 | c.492G>A p.V164= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV99593236; called by muse, mutect2
- TRIM6 | c.1002C>G p.S334= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99546207; called by muse, mutect2, varscan2
- PRND | chr20:4732625 G>A | 3'Flank (SNP) | VAF 12/25 reads (48%) | called by muse, varscan2
- SGCD | c.696+32G>C | Intron (SNP) | VAF 4/8 reads (50%) | catalogued as rs773195873, COSV100548923; called by muse, varscan2
